Somatic mutation profile of tumor specimen 0DNGGM from CCDI case PBCBRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,688 days).
Specimen 0DNGGM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52fa5aa2-9705-406f-a62d-07f6a124e3cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNGGA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557ae0a0-44f2-484a-9f19-584df3f43bbc

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 3, Intron 2, 5'UTR 2, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRL | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 84/942 reads (9%) | catalogued as rs762991211; ClinVar: pathogenic; called by muse, mutect2
- DES | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 50/1060 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1292042317, COSV64660014, COSV64660352; ClinVar: uncertain significance; called by muse, mutect2
- ENDOD1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 41/1246 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs957695086, COSV53590151, COSV53590695; called by muse, mutect2
- GCC2 | c.2996G>T p.R999L | Missense Mutation (SNP) | VAF 124/1716 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776363038, COSV59174312, COSV59176768; called by muse, mutect2
- RHBG | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 301/1178 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs202077403, COSV54802009; called by muse, mutect2, varscan2
- CNBD1 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 207/1422 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTBP2 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 127/1046 reads (12%) | called by muse, mutect2, varscan2
- EPGN | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 104/1280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ETNPPL | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 109/2256 reads (5%) | called by muse, mutect2
- MOGAT3 | c.202_203del p.D68Hfs*58 | Frame Shift Del (DEL) | VAF 158/1712 reads (9%) | called by mutect2, pindel
- PPP1R3F | c.2284C>G p.P762A | Missense Mutation (SNP) | VAF 20/736 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.07); called by muse, mutect2
- PTPRA | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 179/653 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL3 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIGD2 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 403/2099 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TUBA4A | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 209/692 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- WNT5B | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 29/1117 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2
- ZBED1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 336/1028 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2
- CBX7 | c.477C>T p.R159= | Silent (SNP) | VAF 98/1080 reads (9%) | catalogued as rs1013123200, COSV53359685; called by muse, mutect2
- CDH23 | c.5271C>T p.G1757= | Silent (SNP) | VAF 440/892 reads (49%) | catalogued as COSV56458730; called by muse, mutect2, varscan2
- GSTA5 | c.420A>G p.L140= | Silent (SNP) | VAF 174/407 reads (43%) | called by muse, mutect2, varscan2
- TBCEL | c.42T>C p.C14= | Silent (SNP) | VAF 44/1247 reads (4%) | called by muse, mutect2
- TRIM47 | c.36C>T p.C12= | Silent (SNP) | VAF 234/857 reads (27%) | catalogued as rs755956021; called by muse, mutect2, varscan2
- AC097636.1 | c.-41C>T | 5'UTR (SNP) | VAF 207/541 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.748-44C>T | Intron (SNP) | VAF 198/451 reads (44%) | called by muse, mutect2, varscan2
- CCN1 | c.843+32C>A | Intron (SNP) | VAF 125/591 reads (21%) | called by muse, mutect2, varscan2
- PGDP1 | n.676A>G | RNA (SNP) | VAF 88/988 reads (9%) | called by muse, mutect2
- POU2F2 | c.*69C>A | 3'UTR (SNP) | VAF 67/348 reads (19%) | called by muse, mutect2, varscan2
- SHROOM2 | c.-28C>A | 5'UTR (SNP) | VAF 68/246 reads (28%) | called by muse, mutect2, varscan2
